Somatic mutation profile of tumor specimen TCGA-FE-A236-01A (aliquot TCGA-FE-A236-01A-11D-A16O-08) from TCGA case TCGA-FE-A236, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.8 years (12,348 days).
Specimen TCGA-FE-A236-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7417c020-aae1-4b4e-8247-209ccbd2a4fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A236-10A (Blood Derived Normal), aliquot TCGA-FE-A236-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f041a76a-353b-43d8-a7e1-7e5707671ada

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRIX1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV59131605; called by muse, mutect2, varscan2
- CHN1 | c.1007T>C p.I336T | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as rs371299944; called by muse, varscan2
- SCAF8 | c.2011A>G p.S671G | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as COSV63200274; called by muse, mutect2, varscan2
- TMEM100 | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.494); catalogued as COSV70118119; called by muse, mutect2, varscan2
- ZBBX | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV56793662; called by muse, mutect2, varscan2
- MYH13 | c.1179T>A p.N393K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- XPO6 | c.143_157del p.C48_L52del | In Frame Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- CHGB | c.807T>C p.D269= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1568552010, COSV66760930; called by muse, mutect2, varscan2
- CIAO1 | c.186C>T p.R62= | Silent (SNP) | VAF 59/172 reads (34%) | catalogued as rs965291189, COSV51498336; called by muse, mutect2, varscan2
- CTBP1 | chr4:1250701 G>T | 5'Flank (SNP) | VAF 42/100 reads (42%) | called by mutect2, varscan2
